Gene-level copy-number profile of tumor specimen TCGA-55-A493-01A from TCGA case TCGA-55-A493, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.8 years (20,027 days).
Specimen TCGA-55-A493-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.14aca520-8943-453a-974f-0ee169fe45ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A493-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6891e17-0315-4149-beb8-4e68f6ea626f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,950; copy number 2: 22,316; copy number 3: 12,120; copy number 4: 6,156; copy number 5: 140; copy number 6: 137; copy number 34: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A493-01A-11D-A24C-01): tumor purity 0.26, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,969,030–189,969,861, 1 gene, copy number 34: MTAPP2.
- chr12:66,767–5,521,536, 136 genes, copy number 6 (broad region; genes not listed).
- chr12:5,583,797–5,584,085, 1 gene, copy number 6: AC137627.1.
- chr20:61,717,506–64,313,132, 140 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
